Somatic mutation profile of tumor specimen 0DPHAA from CCDI case PBCBGH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (606 days).
Specimen 0DPHAA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ba2f3d0-4df4-4a55-9803-341937dfb0d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPH9W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efcddece-5bb0-4bac-848b-cd8b4061f885

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Intron 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP30 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 54/654 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs202221316, COSV63517278; called by muse, mutect2
- CFHR4 | c.1591G>T p.G531* (on ENST00000367416 / NM_001201551.2; = p.G285* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 202/667 reads (30%) | catalogued as COSV52226308; called by muse, mutect2, varscan2
- DDI1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 122/300 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs138983347, COSV56380960; called by muse, mutect2, varscan2
- DNAH10 | c.1159G>A p.E387K (on ENST00000409039; = p.E326K on NM_207437.3) | Missense Mutation (SNP) | VAF 258/775 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as rs771085939; called by muse, mutect2, varscan2
- LAMA5 | c.5008G>A p.G1670R | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs759428251; called by muse, mutect2, varscan2
- LRP1B | c.13706G>A p.G4569E | Missense Mutation (SNP) | VAF 45/1240 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67262889; called by muse, mutect2
- MXRA5 | c.2124G>T p.E708D | Missense Mutation (SNP) | VAF 68/784 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99476482; called by muse, mutect2
- TRIM72 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 67/662 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs887056269, COSV59066868; called by muse, mutect2
- DEPDC1 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 46/749 reads (6%) | called by muse, mutect2
- DOCK11 | c.2946T>G p.I982M | Missense Mutation (SNP) | VAF 246/754 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FTHL17 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 59/528 reads (11%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- PLA1A | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 199/533 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- SYCP2 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 38/1450 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0.074); called by muse, mutect2
- ARSD | c.1216C>A p.R406= | Silent (SNP) | VAF 210/609 reads (34%) | catalogued as COSV54202087, COSV99471897; called by muse, mutect2, varscan2
- ACVRL1 | c.1377+77C>T | Intron (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- SLC6A14 | c.-44G>T | 5'UTR (SNP) | VAF 83/246 reads (34%) | catalogued as rs1556693295; called by muse, mutect2, varscan2
